Somatic mutation profile of tumor specimen HCM-BROD-0693-C71-01A (aliquot HCM-BROD-0693-C71-01A-15D-A82H-36) from HCMI case HCM-BROD-0693-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.3 years (24,222 days).
Specimen HCM-BROD-0693-C71-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23ab42f0-7102-48d9-b9d3-3a77b1a223bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0693-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0693-C71-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58497a82-9f5b-489e-9744-8a65ee94d7a6

The open-access MAF lists 75 somatic variants for this specimen: 53 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 20, Nonsense Mutation 4, Frame Shift Del 3, Splice Region 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.406T>C p.C136R | Missense Mutation (SNP) | VAF 155/219 reads (71%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs786201044, CM004336, COSV100911109, COSV64289087; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 251/374 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 178/469 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs531290635, COSV101239486, COSV67131269; called by muse, mutect2, varscan2
- ATP8B4 | c.1874G>A p.R625K | Missense Mutation (SNP) | VAF 83/434 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as COSV52721492; called by muse, mutect2, varscan2
- CCER1 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 284/651 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.8); catalogued as COSV62646987; called by muse, mutect2, varscan2
- CETP | c.784C>A p.L262I | Missense Mutation (SNP) | VAF 97/324 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.048); catalogued as rs150475423; called by muse, mutect2, varscan2
- CPA4 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 80/558 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs1162447207; called by muse, mutect2, varscan2
- CXCR4 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 68/694 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1451071577, COSV99602554; called by muse, mutect2
- DNAH6 | c.9622C>T p.R3208* | Nonsense Mutation (SNP) | VAF 88/288 reads (31%) | catalogued as rs963741779; called by muse, varscan2
- F2RL3 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 94/477 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as rs527989109, COSV50186773; called by muse, mutect2, varscan2
- FER | c.1274G>C p.R425P | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV55286183; called by muse, mutect2, varscan2
- FLII | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 26/452 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767251437; called by muse, mutect2
- GLUD2 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 28/383 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs201021827, COSV60152595; called by muse, mutect2
- IGHV1-2 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 24/343 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs561582626; called by muse, mutect2
- KCNK1 | c.750G>A p.T250= | Splice Region (SNP) | VAF 86/217 reads (40%) | catalogued as rs773349901, COSV64036340; called by muse, varscan2
- MAST1 | c.1618C>T p.R540* | Nonsense Mutation (SNP) | VAF 72/333 reads (22%) | catalogued as rs377683590; called by muse, mutect2, varscan2
- MYH4 | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 130/208 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1044500998, COSV55114450; called by muse, mutect2, varscan2
- NCKAP5L | c.3130C>T p.R1044W | Missense Mutation (SNP) | VAF 215/487 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs753774229, COSV60134124; called by muse, mutect2, varscan2
- NDNF | c.1462A>C p.N488H | Missense Mutation (SNP) | VAF 15/440 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV65634981; called by muse, mutect2
- OR4K13 | c.286G>T p.G96* | Nonsense Mutation (SNP) | VAF 135/288 reads (47%) | catalogued as COSV100237924, COSV59859393; called by muse, mutect2, varscan2
- PGM5 | c.1444G>A p.V482M | Missense Mutation (SNP) | VAF 56/340 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as rs782335493, COSV67168507; called by muse, mutect2, varscan2
- RXRG | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 130/288 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs746856217, COSV99071763; called by muse, mutect2, varscan2
- SEC11C | c.112G>T p.A38S | Missense Mutation (SNP) | VAF 114/300 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as COSV55311932; called by muse, varscan2
- SERPINE3 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 31/466 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.543); catalogued as rs376407383; called by muse, mutect2
- SH2D3A | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 104/420 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs767313865, COSV55585796; called by muse, mutect2, varscan2
- SIGLEC11 | c.1801G>A p.V601M | Missense Mutation (SNP) | VAF 62/374 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.197); catalogued as rs752100706; called by muse, mutect2, varscan2
- TRPC6 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 76/335 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); catalogued as rs1485520621; called by muse, mutect2, varscan2
- ZC3H4 | c.783G>A p.M261I | Missense Mutation (SNP) | VAF 117/627 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs750038223, COSV53413219; called by muse, mutect2, varscan2
- ZNF311 | c.1901A>G p.H634R | Missense Mutation (SNP) | VAF 192/593 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs759706820; called by muse, mutect2, varscan2
- ADH7 | c.17A>C p.Q6P | Missense Mutation (SNP) | VAF 21/417 reads (5%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.04); called by muse, mutect2
- C9orf131 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 112/313 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COL5A3 | c.4771_4772del p.K1591Vfs*2 | Frame Shift Del (DEL) | VAF 46/281 reads (16%) | called by mutect2, pindel, varscan2
- DCBLD2 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 96/334 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXJ3 | c.926_929del p.S309Nfs*4 | Frame Shift Del (DEL) | VAF 24/111 reads (22%) | called by mutect2, pindel, varscan2
- FRY | c.5966G>A p.G1989D | Missense Mutation (SNP) | VAF 27/412 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.915); called by muse, mutect2
- FUBP1 | c.132A>T p.K44N | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HOXC12 | c.23A>T p.N8I | Missense Mutation (SNP) | VAF 94/259 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MOBP | c.314G>A p.R105H (on ENST00000420739; = p.R129H on NM_001278322.2) | Missense Mutation (SNP) | VAF 264/746 reads (35%) | PolyPhen benign (0.108); called by muse, varscan2
- MYH4 | c.5689C>A p.L1897I | Missense Mutation (SNP) | VAF 159/233 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- NEFL | c.664T>C p.F222L | Missense Mutation (SNP) | VAF 158/459 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- OR2A14 | c.228T>G p.Y76* | Nonsense Mutation (SNP) | VAF 34/486 reads (7%) | called by muse, mutect2
- OR51I2 | c.136C>A p.L46M | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR6K6 | c.42G>T p.R14S | Missense Mutation (SNP) | VAF 127/399 reads (32%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDE2A | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 83/374 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POF1B | c.1164G>T p.Q388H | Missense Mutation (SNP) | VAF 43/62 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PPEF2 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 172/419 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- SCN8A | c.1789C>T p.R597C | Missense Mutation (SNP) | VAF 16/553 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- SEMG2 | c.1112A>G p.K371R | Missense Mutation (SNP) | VAF 61/316 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- SND1 | c.2036C>T p.S679F | Missense Mutation (SNP) | VAF 215/807 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- STAT4 | c.1843T>C p.S615P | Missense Mutation (SNP) | VAF 17/412 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.443); called by muse, mutect2
- SUGP2 | c.1968_1969del p.A657Sfs*75 | Frame Shift Del (DEL) | VAF 76/493 reads (15%) | called by pindel, varscan2
- VIM | c.13T>G p.S5A | Missense Mutation (SNP) | VAF 202/257 reads (79%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF729 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- ADGRB1 | c.198G>A p.S66= | Silent (SNP) | VAF 218/544 reads (40%) | catalogued as rs752538490; called by muse, mutect2, varscan2
- ANO8 | c.3537C>T p.A1179= | Silent (SNP) | VAF 22/147 reads (15%) | called by mutect2, varscan2
- AP2B1 | c.378C>T p.L126= | Silent (SNP) | VAF 220/306 reads (72%) | catalogued as rs1378297348; called by muse, mutect2, varscan2
- BMP5 | c.291G>A p.S97= | Silent (SNP) | VAF 84/508 reads (17%) | catalogued as rs201787809; called by muse, mutect2, varscan2
- C9orf131 | c.942G>A p.L314= | Silent (SNP) | VAF 151/358 reads (42%) | called by muse, mutect2, varscan2
- CACNA1F | c.5685C>T p.A1895= | Silent (SNP) | VAF 174/208 reads (84%) | catalogued as rs782554706, COSV100544243; called by muse, mutect2, varscan2
- CDC42BPG | c.3933C>T p.H1311= | Silent (SNP) | VAF 67/242 reads (28%) | catalogued as rs760868480, COSV61348195; called by muse, mutect2, varscan2
- COL5A1 | c.2106C>T p.D702= | Silent (SNP) | VAF 135/333 reads (41%) | catalogued as rs534445410, COSV65666223; called by muse, mutect2, varscan2
- COL6A2 | c.1920C>T p.N640= | Silent (SNP) | VAF 240/525 reads (46%) | catalogued as rs143819480; ClinVar: likely benign; called by muse, mutect2, varscan2
- H4C11 | c.168C>T p.R56= | Silent (SNP) | VAF 68/293 reads (23%) | catalogued as rs1201056191; called by muse, mutect2, varscan2
- MPL | c.372C>G p.V124= | Silent (SNP) | VAF 123/277 reads (44%) | called by muse, mutect2, varscan2
- OR2L13 | c.357C>T p.Y119= | Silent (SNP) | VAF 194/490 reads (40%) | catalogued as rs1438157332, COSV63553802; called by muse, mutect2, varscan2
- POM121L2 | c.3039C>T p.G1013= | Silent (SNP) | VAF 149/461 reads (32%) | catalogued as rs768139368, COSV66277577; called by muse, mutect2, varscan2
- PTPN23 | c.3655C>T p.L1219= | Silent (SNP) | VAF 30/606 reads (5%) | called by muse, mutect2
- RBPMS2 | c.426G>A p.L142= | Silent (SNP) | VAF 51/329 reads (16%) | called by muse, mutect2, varscan2
- SLC22A16 | c.1200C>T p.P400= | Silent (SNP) | VAF 122/321 reads (38%) | catalogued as rs373105261; called by muse, varscan2
- SLC5A4 | c.1182G>A p.L394= | Silent (SNP) | VAF 36/424 reads (8%) | called by muse, mutect2
- THSD7B | c.786C>T p.S262= | Silent (SNP) | VAF 109/330 reads (33%) | catalogued as rs576768669, COSV55675824, COSV55679461; called by muse, mutect2, varscan2
- TRRAP | c.8565C>T p.C2855= (on ENST00000359863 / NM_001244580.1; = p.C2837= on NM_003496.3) | Silent (SNP) | VAF 150/775 reads (19%) | catalogued as rs777625422, COSV62840828; called by muse, mutect2, varscan2
- ZBTB4 | c.1728C>T p.G576= | Silent (SNP) | VAF 255/403 reads (63%) | catalogued as rs373767560; called by muse, mutect2, varscan2
- RNU6-1178P | chr17:20895967 C>T | 5'Flank (SNP) | VAF 170/272 reads (63%) | catalogued as rs758956725; called by muse, mutect2, varscan2
- WBP2NL | c.*790G>A | 3'UTR (SNP) | VAF 13/80 reads (16%) | called by muse, mutect2, varscan2
